Somatic mutation profile of tumor specimen TCGA-ER-A19N-06A (aliquot TCGA-ER-A19N-06A-11D-A197-08) from TCGA case TCGA-ER-A19N, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.9 years (17,480 days).
Specimen TCGA-ER-A19N-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfe26664-6fec-441a-9475-5cb864b5b69e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19N-10A (Blood Derived Normal), aliquot TCGA-ER-A19N-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4abce1fa-2578-4d0e-8557-70eb93cd878a

The open-access MAF lists 522 somatic variants for this specimen: 337 protein-altering or splice-affecting, 168 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 303, Silent 168, Nonsense Mutation 22, Intron 8, Splice Region 7, Splice Site 4, 3'UTR 3, RNA 3, 5'Flank 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K2 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs121434498, CM080435, CM086853, COSV53562382, COSV53564387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 41/139 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59382802; called by muse, mutect2, varscan2
- ABCA10 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 18/187 reads (10%) | catalogued as rs866595174, COSV52218114; called by mutect2, varscan2
- ABCB11 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55585178; called by muse, mutect2, varscan2
- ABCC10 | c.3368C>T p.T1123I (on ENST00000372530 / NM_001198934.2; = p.T1095I on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs776953080, COSV99766888; called by muse, mutect2, varscan2
- ABCC9 | c.2675G>A p.R892K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53962436; called by muse, mutect2
- ABHD16A | c.1530del p.F511Sfs*9 | Frame Shift Del (DEL) | VAF 92/288 reads (32%) | catalogued as COSV101013120; called by mutect2, pindel, varscan2
- ACAN | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as rs746352037, COSV61355652; called by mutect2, varscan2
- ACBD6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.437); catalogued as rs1370783650, COSV62571572; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV58441269; called by muse, mutect2, varscan2
- ADORA2A | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58377875; called by muse, mutect2, varscan2
- AFM | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.64); catalogued as COSV56918952; called by mutect2, varscan2
- AL645922.1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs746257765, COSV100190872; called by muse, mutect2, varscan2
- ALDH3A2 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV51565544; called by mutect2, varscan2
- ALPK2 | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs758307277, COSV64490250; called by mutect2, varscan2
- ALPK2 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV64490260; called by muse, mutect2, varscan2
- ANGPTL5 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV57531776; called by muse, mutect2, varscan2
- ANK3 | c.9145C>T p.P3049S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs1009329743, COSV55043871; called by muse, mutect2, varscan2
- ANKRD35 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs376866282; called by mutect2, varscan2
- ANO2 | c.964G>A p.D322N (on ENST00000356134 / NM_001278597.3; = p.D326N on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs781540782, COSV59007575; called by mutect2, varscan2
- ANXA10 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs772678367, COSV63737962; called by mutect2, varscan2
- AOAH | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV51735544; called by muse, mutect2, varscan2
- APOB | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV51922924; called by muse, mutect2, varscan2
- ARFGEF1 | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as rs1268876505, COSV51602298; called by muse, mutect2, varscan2
- ARHGAP19 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs915941555, COSV57391380; called by muse, mutect2, varscan2
- ARHGAP36 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV52263750, COSV99357835; called by mutect2, varscan2
- ARHGEF35 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV65312384; called by mutect2, varscan2
- ARHGEF7 | c.1180C>T p.P394S (on ENST00000375741 / NM_001113511.2; = p.P216S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV99521198; called by muse, mutect2, varscan2
- ASH1L | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV64205384; called by muse, varscan2
- ASMTL | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs781049994, COSV101187712; called by mutect2, varscan2
- ASTN1 | c.3648G>A p.R1216= | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as COSV62490720; called by muse, mutect2, varscan2
- ASTN1 | c.1440G>A p.G480= | Splice Region (SNP) | VAF 27/174 reads (16%) | catalogued as COSV56061295; called by muse, varscan2
- AXDND1 | c.2664T>G p.D888E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV62639585; called by muse, mutect2
- B3GALT6 | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV99767438; called by mutect2, varscan2
- BAAT | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200347226, COSV52287019; ClinVar: uncertain significance; called by mutect2, varscan2
- BCO1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs535639302, COSV50728006; called by mutect2, varscan2
- BDKRB2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.254); catalogued as COSV60014278; called by muse, varscan2
- BDKRB2 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs764968612, COSV60014284; called by muse, varscan2
- BEST3 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV58298719; called by muse, varscan2
- C1orf127 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as rs1435441154, COSV65436365; called by muse, mutect2, varscan2
- C9orf135 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV65874528; called by muse, mutect2, varscan2
- CALB1 | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55366437; called by muse, mutect2
- CAMKK2 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.561); catalogued as COSV61212780; called by muse, mutect2, varscan2
- CAPN5 | c.1594C>T p.P532S (on ENST00000456580; = p.P492S on NM_004055.5) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs782761209, COSV53685605; called by muse, mutect2, varscan2
- CASD1 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.19); catalogued as COSV51970624, COSV99802072; called by muse, mutect2, varscan2
- CASP7 | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV61880990; called by muse, varscan2
- CCR4 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447551, COSV58381359; called by muse, mutect2, varscan2
- CD163 | c.1952A>C p.H651P | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV63129332; called by muse, mutect2, varscan2
- CD163L1 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV58010812; called by muse, mutect2, varscan2
- CD300A | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV60409469; called by muse, mutect2, varscan2
- CD300A | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as COSV60409478; called by mutect2, varscan2
- CDH17 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50325607; called by muse, mutect2, varscan2
- CDH9 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50251836, COSV50254045; called by mutect2, varscan2
- CDKN2AIP | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV56626721; called by muse, mutect2, varscan2
- CHST1 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57321683; called by muse, varscan2
- CLCN6 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.906); catalogued as COSV56737841; called by muse, mutect2
- CLRN2 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs371963212, COSV72512636; called by mutect2, varscan2
- CNTN4 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs771875004, COSV61867705; called by mutect2, varscan2
- CNTN5 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54280124; called by muse, mutect2, varscan2
- CNTROB | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV66607447; called by muse, mutect2, varscan2
- COL20A1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV58911570; called by mutect2, varscan2
- COL4A1 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65421261; called by muse, mutect2, varscan2
- COPG1 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1252035155, COSV100135431; called by muse, mutect2
- COPS2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV54644157; called by muse, mutect2, varscan2
- COX6B1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1451939305, COSV55836955; called by muse, mutect2, varscan2
- CRMP1 | c.1235G>A p.W412* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV61478174; called by muse, mutect2, varscan2
- CRP | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760410118, COSV54812566, COSV54812711; called by mutect2, varscan2
- CRTAP | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV58012940; called by muse, mutect2, varscan2
- CSH2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61080493; called by mutect2, varscan2
- CSH2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100400167; called by mutect2, varscan2
- CSMD1 | c.9307C>T p.P3103S (on ENST00000520002; = p.P3102S on NM_033225.6) | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV59280734; called by muse, mutect2, varscan2
- CSMD3 | c.9419C>G p.S3140C (on ENST00000297405 / NM_001363185.1; = p.S2971C on NM_052900.3) | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52101231, COSV52285833; called by muse, mutect2, varscan2
- CX3CR1 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64192971; called by muse, varscan2
- DAB1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV59722103; called by mutect2, varscan2
- DCAF12L1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64421165; called by muse, mutect2, varscan2
- DCLK1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55171237, COSV55176899; called by muse, mutect2, varscan2
- DDIAS | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100231072; called by mutect2, varscan2
- DEFB124 | c.60G>A p.G20= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58342668; called by muse, mutect2, varscan2
- DHX16 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV64563005; called by muse, varscan2
- DIDO1 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56613531; called by muse, mutect2
- DISP3 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV53820142; called by muse, mutect2, varscan2
- DLG1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV58377816; called by muse, mutect2, varscan2
- DLG1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV58377833; called by muse, mutect2, varscan2
- DLX4 | c.566G>A p.G189E (on ENST00000240306 / NM_138281.3; = p.G117E on NM_001934.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV53590969; called by muse, varscan2
- DMXL2 | c.8176C>T p.Q2726* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV51840667; called by mutect2, varscan2
- DNAH1 | c.1666T>C p.F556L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV70226357; called by muse, mutect2, varscan2
- DNAH2 | c.9907G>A p.D3303N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV66716221; called by muse, mutect2, varscan2
- DNAH5 | c.13117C>T p.P4373S | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV54203644; called by muse, mutect2, varscan2
- DNAH5 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs560939419, COSV54203651, COSV99453001; called by mutect2, varscan2
- DOCK1 | c.4307G>T p.R1436L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV54729572, COSV54731700; called by muse, mutect2, varscan2
- DOCK10 | c.4322T>C p.L1441S | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV51347721; called by muse, mutect2, varscan2
- DRC3 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV58261647; called by muse, mutect2, varscan2
- DSEL | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 24/139 reads (17%) | catalogued as COSV59489456; called by mutect2, varscan2
- DSG3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs772960249, COSV57124134; called by mutect2, varscan2
- DSTYK | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV65685261; called by muse, mutect2, varscan2
- DYNAP | c.419G>A p.G140E (on ENST00000321600; = p.G114E on NM_173629.3) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.303); catalogued as rs1266252672, COSV58665973; called by muse, mutect2, varscan2
- DZIP1L | c.1661A>G p.K554R | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs746287400, COSV100551221; called by muse, mutect2, varscan2
- EBF3 | c.1197G>A p.E399= (on ENST00000355311 / NM_001375392.1; = p.E390= on NM_001005463.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as COSV62471744, COSV62478117; called by muse, mutect2, varscan2
- EML1 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV51741359; called by mutect2, varscan2
- EP400 | c.2986A>T p.I996F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57762465; called by muse, mutect2, varscan2
- EPHA6 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67558538; called by muse, mutect2, varscan2
- EPHB1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67653857; called by muse, mutect2, varscan2
- ETAA1 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99712638; called by muse, mutect2, varscan2
- ETAA1 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV99712639; called by muse, mutect2, varscan2
- EXOSC10 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58663606; called by muse, mutect2, varscan2
- EYA2 | c.153C>T p.S51= | Splice Region (SNP) | VAF 8/77 reads (10%) | catalogued as COSV57938050; called by muse, mutect2, varscan2
- FAM81B | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV51980554; called by muse, mutect2, varscan2
- FBN1 | c.8335G>A p.E2779K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100353965, COSV57309148; called by muse, mutect2, varscan2
- FBXO32 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.233); catalogued as COSV54890099; called by muse, mutect2, varscan2
- FCER1A | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV63666491; called by muse, mutect2, varscan2
- FGFR2 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60639631; called by muse, mutect2, varscan2
- FMO3 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV63006443; called by muse, varscan2
- FN1 | c.3332C>T p.P1111L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60546396; called by muse, mutect2, varscan2
- FOLH1 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99922862, COSV99923244; called by mutect2, varscan2
- FOXM1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs769577617, COSV100700839, COSV61205191; called by mutect2, varscan2
- FRMD7 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53744584; called by muse, mutect2, varscan2
- FRMPD2 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs746192606, COSV59714920; called by mutect2, varscan2
- FRY | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs200692607, COSV66568144; called by mutect2, varscan2
- GALNT8 | c.1058A>G p.K353R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.085); catalogued as COSV52894500; called by muse, mutect2, varscan2
- GALNTL6 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746294876, COSV71826038; called by muse, mutect2, varscan2
- GAREM1 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.588); catalogued as rs757157228, COSV52505784; called by mutect2, varscan2
- GATA3 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs1268951338, COSV60515426; called by muse, mutect2, varscan2
- GBP4 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63252871; called by mutect2, varscan2
- GCOM1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV51088038; called by muse, mutect2, varscan2
- GNAT3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.232); catalogued as COSV68067822; called by mutect2, varscan2
- GNG4 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as rs774689533, COSV63998865; called by mutect2, varscan2
- GPC5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65576303; called by muse, mutect2, varscan2
- GPR137 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100464073; called by mutect2, varscan2
- GRIA1 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53588694; called by muse, mutect2, varscan2
- GRN | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV50009486, COSV99274658; called by mutect2, varscan2
- GRN | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99274661, COSV99274911; called by mutect2, varscan2
- GUCY2C | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV53786678; called by mutect2, varscan2
- HAL | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54116421; called by muse, varscan2
- HERC2 | c.4964G>A p.R1655K | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55307148, COSV55310031; called by muse, mutect2, varscan2
- HK3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV52836803; called by muse, mutect2, varscan2
- HMBOX1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55065813; called by muse, mutect2, varscan2
- IKBKE | c.2041C>T p.L681F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV65622818; called by muse, mutect2, varscan2
- IL36B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs755811144, COSV52084410; called by mutect2, varscan2
- IL36RN | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV100697232; called by muse, mutect2, varscan2
- INTU | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV56538253; called by muse, mutect2, varscan2
- IPMK | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.551); catalogued as COSV64243370; called by muse, mutect2, varscan2
- IRAG2 | c.2890G>A p.E964K (on ENST00000636465; = p.E9K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV63137474; called by muse, mutect2, varscan2
- ITM2B | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV66034827; called by muse, mutect2, varscan2
- JAKMIP3 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53819614; called by muse, mutect2, varscan2
- JMJD1C | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67857794; called by muse, mutect2, varscan2
- JMY | c.2149C>T p.Q717* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101268054, COSV68659338; called by muse, mutect2, varscan2
- KANK4 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as rs770081998, COSV58091947, COSV58094081; called by mutect2, varscan2
- KCNH1 | c.2228G>A p.R743K (on ENST00000271751 / NM_172362.3; = p.R716K on NM_002238.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs975280418, COSV55069419; called by muse, mutect2, varscan2
- KCNH6 | c.524A>T p.Y175F | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV59000686; called by muse, mutect2, varscan2
- KCNJ6 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55709373; called by muse, mutect2, varscan2
- KCNJ8 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.026); catalogued as COSV53715193; called by muse, mutect2, varscan2
- KDR | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55759613; called by muse, mutect2, varscan2
- KIAA1549L | c.5380G>A p.E1794K (on ENST00000321505; = p.E2091K on NM_012194.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100380761, COSV58581613; called by muse, mutect2, varscan2
- KLK5 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs766308131, COSV60449504; called by muse, mutect2, varscan2
- KRBA2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV100497621; called by mutect2, varscan2
- KRBA2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100497623; called by muse, mutect2, varscan2
- KRT1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as rs751668925, COSV52864837; called by mutect2, varscan2
- KRT3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs570472655, COSV58814556; called by mutect2, varscan2
- KRTAP3-3 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV66956557; called by muse, mutect2, varscan2
- L3MBTL4 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53113059; called by muse, mutect2, varscan2
- LAIR1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV57305912; called by muse, mutect2, varscan2
- LCT | c.720G>A p.Q240= | Splice Region (SNP) | VAF 42/293 reads (14%) | catalogued as COSV51544044; called by muse, mutect2, varscan2
- LIFR | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs193221561, COSV54684390; called by muse, mutect2, varscan2
- LPA | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV60296409; called by mutect2, varscan2
- LRRIQ1 | c.4423C>T p.P1475S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67825818; called by muse, mutect2, varscan2
- LVRN | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63495922; called by muse, mutect2
- MAML2 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1233901902, COSV73262674; called by muse, mutect2, varscan2
- MCHR2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55999634; called by muse, varscan2
- MIER1 | c.1534G>A p.D512N (on ENST00000355356 / NM_001077701.3; = p.D529N on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV62529110; called by mutect2, varscan2
- MKI67 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.498); catalogued as COSV64072511; called by muse, mutect2, varscan2
- MPP7 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV61729963; called by mutect2, varscan2
- MRGPRX4 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV58589763; called by muse, mutect2, varscan2
- MUC16 | c.25474G>A p.E8492K | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.205); catalogued as COSV67444218; called by muse, mutect2, varscan2
- MUC16 | c.8826G>T p.M2942I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67444234; called by mutect2, varscan2
- MYO3A | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56319572; called by muse, mutect2, varscan2
- NACC2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99508242; called by muse, varscan2
- NAP1L3 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV59073446, COSV59073657; called by muse, mutect2, varscan2
- NCAPG | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.539); catalogued as COSV52268550; called by muse, mutect2, varscan2
- NEB | c.15028C>T p.R5010W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533233215, COSV50809347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP10 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60778641; called by mutect2, varscan2
- NLRP7 | c.2485C>T p.R829C (on ENST00000340844 / NM_206828.3; = p.R801C on NM_139176.3) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs758672812, COSV60170921; called by muse, mutect2, varscan2
- NPAP1 | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV61504384; called by mutect2, varscan2
- NPVF | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as COSV56060110; called by muse, mutect2, varscan2
- NUP210 | c.4358T>G p.L1453R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99595779; called by muse, mutect2, varscan2
- NXT1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54782729; called by muse, mutect2, varscan2
- OPTC | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65867234; called by muse, mutect2, varscan2
- OR10G7 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57865567; called by mutect2, varscan2
- OR10J5 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58384830; called by muse, varscan2
- OR10K2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs549288316, COSV100149447, COSV59220398; called by mutect2, varscan2
- OR13C4 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52925826; called by muse, mutect2, varscan2
- OR13F1 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV58250688; called by muse, mutect2, varscan2
- OR1F1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV58960347; called by muse, mutect2, varscan2
- OR4C11 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155301, COSV56352135; called by muse, mutect2, varscan2
- OR51V1 | c.193T>G p.F65V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV58314097; called by muse, mutect2, varscan2
- OR52E2 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs267602936, COSV58611784; called by mutect2, varscan2
- OR5H6 | c.321G>A p.M107I (on ENST00000642105; = p.M91I on NM_001005479.2) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs764734582, COSV67351016; called by mutect2, varscan2
- OTOGL | c.2827C>T p.P943S (on ENST00000547103; = p.P934S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1421669287, COSV72005596; called by muse, varscan2
- OXGR1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV53656689; called by muse, mutect2, varscan2
- PABPC4 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV63293236; called by mutect2, varscan2
- PAIP2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV54524824; called by muse, mutect2, varscan2
- PCDH11Y | c.2959C>T p.P987S (on ENST00000400457 / NM_032973.2; = p.P976S on NM_032971.3) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53073572; called by muse, mutect2, varscan2
- PCDH12 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51519103; called by muse, mutect2, varscan2
- PCDH18 | c.515A>T p.H172L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as COSV61266319; called by muse, mutect2, varscan2
- PCDHA12 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as COSV56477180; called by muse, mutect2
- PCDHB10 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53375292; called by muse, mutect2, varscan2
- PCDHGA3 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.301); catalogued as COSV53897763; called by muse, mutect2, varscan2
- PCDHGA5 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as rs766850721, COSV53897784, COSV99548920; called by mutect2, varscan2
- PCLO | c.12692C>T p.S4231F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV61615595; called by muse, mutect2, varscan2
- PCNX2 | c.4910G>A p.G1637E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs940290160, COSV50781651; called by muse, mutect2, varscan2
- PDCL2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55259160; called by muse, mutect2, varscan2
- PDE6B | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as COSV55323753; called by mutect2, varscan2
- PDE7B | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57492709; called by muse, mutect2, varscan2
- PDZD2 | c.7663A>G p.S2555G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV56850479; called by muse, mutect2, varscan2
- PDZRN4 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101284521; called by muse, mutect2, varscan2
- PEAR1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV52770716; called by mutect2, varscan2
- PEX1 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.406); catalogued as COSV50394578; called by muse, mutect2, varscan2
- PIWIL1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751181793, COSV55344004; called by mutect2, varscan2
- PKD1L2 | c.1672-1G>A p.X558_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV55157998; called by muse, mutect2, varscan2
- PLCL2 | c.3185G>A p.W1062* (on ENST00000615277 / NM_001144382.2; = p.W936* on NM_015184.5) | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV67620477; called by muse, mutect2, varscan2
- PLS3 | c.1254T>A p.H418Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.752); catalogued as COSV56776314; called by mutect2, varscan2
- POLA2 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55480749; called by muse, mutect2, varscan2
- PPARGC1A | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53524371; called by muse, mutect2, varscan2
- PPARGC1B | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475033651, COSV58525933; called by mutect2, varscan2
- PPP1R9A | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56881124; called by muse, mutect2, varscan2
- PRB3 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs764834666, COSV54387759; called by muse, varscan2
- PRKCG | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54723654; called by mutect2, varscan2
- PROX2 | c.1421G>A p.R474H (on ENST00000556489 / NM_001243007.1; = p.R247H on NM_001080408.2) | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776641638, CM1211470, COSV71519962; called by muse, mutect2, varscan2
- PSG9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs866050640, COSV52483314; called by muse, varscan2
- PTH2R | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.78); catalogued as COSV55913721; called by mutect2, varscan2
- PTPN20 | c.1219G>A p.D407N (on ENST00000374339 / NM_001042357.4; = p.R223Q on NM_015605.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs933689605; called by mutect2, varscan2
- PTPN22 | c.2225C>T p.P742L (on ENST00000359785 / NM_001193431.2; = p.P687L on NM_012411.5) | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV63084302; called by muse, mutect2, varscan2
- RAPGEF4 | c.2006A>C p.E669A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as COSV51379293; called by muse, varscan2
- REN | c.699G>A p.E233= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as COSV65817303; called by muse, mutect2, varscan2
- RGL1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV58978624; called by muse, mutect2
- RGS7 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV58530557; called by mutect2, varscan2
- RIC3 | c.692C>T p.P231L (on ENST00000309737 / NM_001206671.4; = p.P230L on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867662746, COSV58300167; called by muse, mutect2
- RIMS4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV65719085; called by muse, mutect2, varscan2
- RIN2 | c.2785C>T p.P929S (on ENST00000255006 / NM_001242581.1; = p.P880S on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV54784086; called by muse, mutect2, varscan2
- RNASET2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.127); catalogued as rs753772218, COSV50351133; called by muse, mutect2, varscan2
- ROBO2 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV59896281; called by muse, varscan2
- RPS6KC1 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV65297099; called by muse, mutect2, varscan2
- RTEL1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV58890655; called by muse, mutect2
- RTN2 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs895596505, COSV55592450; called by mutect2, varscan2
- RTTN | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV55341119; called by muse, mutect2, varscan2
- S100A8 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100907091; called by muse, mutect2, varscan2
- SBK2 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs559033119, COSV60013209; called by mutect2, varscan2
- SCN11A | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100182562, COSV56565569; called by muse, mutect2, varscan2
- SEC14L5 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV52036250; called by mutect2, varscan2
- SEC24C | c.3103C>T p.L1035F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV59539760; called by muse, mutect2, varscan2
- SEC31A | c.2503-1G>A p.X835_splice (on ENST00000355196 / NM_001318120.1; = p.X796_splice on NM_016211.4) | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as COSV52341224; called by muse, mutect2
- SEMA3E | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57079439, COSV57110813; called by mutect2, varscan2
- SERPINB11 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1355365574, COSV66956404; called by muse, mutect2
- SETX | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56378762; called by mutect2, varscan2
- SF3B3 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV56785178; called by muse, mutect2, varscan2
- SH3BGR | c.624+2T>G p.X208_splice | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as COSV61321632; called by muse, mutect2, varscan2
- SHROOM4 | c.3101C>T p.S1034L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56784077; called by mutect2, varscan2
- SIAH3 | c.421A>T p.I141F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV68551359; called by muse, mutect2
- SIGLEC12 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs868615338, COSV52459250; called by muse, mutect2, varscan2
- SIRPB1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.764); catalogued as rs747900541, COSV53537349, COSV53541567; called by muse, mutect2, varscan2
- SLC29A2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV100237036; called by muse, varscan2
- SLC45A4 | c.1163G>A p.G388D (on ENST00000517878 / NM_001286646.2; = p.G337D on NM_001080431.2) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV50132950; called by muse, mutect2, varscan2
- SLC4A1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs267604901, COSV52258295; called by muse, mutect2, varscan2
- SLC5A8 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs866560711, COSV73310357; called by mutect2, varscan2
- SLC66A1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV64320778; called by muse, mutect2, varscan2
- SLC9C1 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59884871; called by muse, mutect2, varscan2
- SLC9C1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs762076820, COSV59884880; called by mutect2, varscan2
- SLCO5A1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52653534; called by muse, mutect2, varscan2
- SLITRK4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100567307, COSV62022078; called by mutect2, varscan2
- SOCS3 | c.239T>C p.F80S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100434469; called by muse, mutect2
- SORL1 | c.6026G>A p.G2009E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.757); catalogued as rs766163770, COSV52749128; called by muse, mutect2, varscan2
- SP140L | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV54741128; called by muse, mutect2
- SPAG17 | c.3807T>G p.Y1269* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV60452690; called by muse, varscan2
- SPAG6 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57617869; called by muse, mutect2, varscan2
- SPATA25 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs990510253, COSV99509726; called by muse, mutect2, varscan2
- SPEF2 | c.4291A>G p.S1431G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57426955; called by muse, mutect2, varscan2
- SPHKAP | c.3109C>A p.L1037I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60868405, COSV60879780; called by mutect2, varscan2
- SPRR1B | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV61067412; called by muse, mutect2, varscan2
- SRGAP3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV64530320; called by muse, mutect2, varscan2
- SSTR1 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV57454912; called by mutect2, varscan2
- ST18 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52484101; called by muse, mutect2, varscan2
- STARD8 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99366408; called by mutect2, varscan2
- STEAP4 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57328022; called by muse, mutect2, varscan2
- STK31 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63453951; called by muse, mutect2, varscan2
- STK36 | c.2093G>A p.R698K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV99831136; called by muse, mutect2, varscan2
- STRA6 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV60584391; called by muse, mutect2, varscan2
- SUCNR1 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 29/186 reads (16%) | catalogued as COSV62911813; called by muse, mutect2, varscan2
- SULF1 | c.2569A>G p.S857G | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV52673055; called by muse, mutect2, varscan2
- TCHHL1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV64284839; called by muse, mutect2, varscan2
- TCHHL1 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as rs556122990, COSV64284845; called by muse, mutect2, varscan2
- TDRD5 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV54238766; called by mutect2, varscan2
- TENM3 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV69299157, COSV69310850; called by muse, mutect2, varscan2
- TENM3 | c.7331G>A p.W2444* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV69299169; called by muse, mutect2, varscan2
- TFEB | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57823456; called by mutect2, varscan2
- THAP4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1414783327, COSV58709277; called by muse, mutect2, varscan2
- TKFC | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427084373, COSV99582317; called by mutect2, varscan2
- TKFC | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99582318; called by muse, mutect2, varscan2
- TLL2 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs987028272, COSV63570664; called by muse, mutect2, varscan2
- TLR2 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs924802006, COSV52604936; called by muse, mutect2, varscan2
- TLR4 | c.1037C>T p.P346L (on ENST00000355622 / NM_138554.5; = p.P306L on NM_003266.4) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV62922418; called by muse, mutect2, varscan2
- TMPRSS3 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52299941; called by muse, varscan2
- TOMM70 | c.1653G>T p.M551I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV52522166; called by mutect2, varscan2
- TOMM70 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV52522178; called by muse, mutect2, varscan2
- TOP2A | c.817A>G p.M273V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1246819670, COSV70732005; called by muse, mutect2, varscan2
- TPCN1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs966838154, COSV59232220; called by muse, mutect2, varscan2
- TRIM67 | c.2161G>C p.V721L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.66); catalogued as COSV64158085; called by muse, mutect2, varscan2
- TSC2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867879148, CD991908, COSV99553165; called by muse, mutect2, varscan2
- TTN | c.47390G>A p.G15797E (on ENST00000591111; = p.G8373E on NM_003319.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | PolyPhen benign (0.006); catalogued as rs1356720044, COSV59883740, COSV59927186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.30580G>A p.E10194K (on ENST00000591111; = p.E9267K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | PolyPhen benign (0); catalogued as rs1238948061, COSV59883774; called by muse, mutect2, varscan2
- TTN | c.6073G>A p.E2025K (on ENST00000591111; = p.E1979K on NM_003319.4) | Missense Mutation (SNP) | VAF 50/138 reads (36%) | PolyPhen benign (0.254); catalogued as COSV59861019, COSV59883795; called by mutect2, varscan2
- TUBAL3 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554813786, COSV66813897; called by mutect2, varscan2
- USP36 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV61750100; called by muse, mutect2, varscan2
- USP39 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60380742; called by muse, mutect2, varscan2
- USP40 | c.3607C>T p.L1203F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as COSV99296025; called by mutect2, varscan2
- USP54 | c.1994G>T p.S665I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60439633; called by muse, mutect2, varscan2
- VPS33A | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs766589793, COSV57355984; called by muse, varscan2
- VWA2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs760573254, COSV53904878; called by muse, mutect2, varscan2
- WDR11 | c.3382C>T p.L1128F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV54785326; called by muse, mutect2, varscan2
- WDR31 | c.971G>A p.G324E (on ENST00000374193 / NM_001006615.3; = p.G323E on NM_145241.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231330962, COSV100516636, COSV100516794; called by muse, mutect2, varscan2
- WDR93 | c.1937G>A p.R646K | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV51530422; called by muse, mutect2, varscan2
- WFDC8 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs1274785982, COSV51488535; called by muse, mutect2, varscan2
- ZBBX | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56782473; called by mutect2, varscan2
- ZBTB39 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as rs1426940725, COSV55627791; called by muse, mutect2, varscan2
- ZGPAT | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780681193, COSV56651222; called by mutect2, varscan2
- ZIM3 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54139863; called by muse, mutect2, varscan2
- ZNF292 | c.7067C>T p.P2356L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV60535495; called by muse, mutect2, varscan2
- ZNF425 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65200540; called by muse, mutect2, varscan2
- ZNF480 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as rs775486074, COSV57994569; called by mutect2, varscan2
- ZNF71 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60146414; called by muse, varscan2
- ZNF883 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV71308868; called by muse, varscan2
- ZP3 | c.679G>C p.A227P (on ENST00000394857 / NM_001110354.2; = p.A176P on NM_007155.6) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV60630376, COSV60632486; called by muse, mutect2, varscan2
- ZPLD1 | c.478G>A p.E160K (on ENST00000466937 / NM_001329788.1; = p.E176K on NM_175056.2) | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV60351814; called by muse, mutect2, varscan2
- ZSCAN4 | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as rs1209035158, COSV58998756; called by muse, mutect2, varscan2
- IGKV2-30 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- LAMC1 | c.2728C>T p.H910Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by mutect2, varscan2
- NCAPD2 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- ZNF658 | c.2449C>T p.Q817* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | called by mutect2, varscan2
- ABCC10 | c.3369C>T p.T1123= (on ENST00000372530 / NM_001198934.2; = p.T1095= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV99766891; called by muse, mutect2, varscan2
- ABHD16A | c.645C>T p.T215= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV65451334; called by muse, mutect2, varscan2
- ADAM19 | c.1710G>A p.A570= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs143295058, COSV99976833; called by mutect2, varscan2
- ADCY10 | c.927G>A p.E309= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV63238501; called by muse, varscan2
- ADGRL3 | c.27C>T p.F9= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV72265571; called by mutect2, varscan2
- AHNAK | c.6939C>T p.S2313= | Silent (SNP) | VAF 34/223 reads (15%) | catalogued as COSV57203450; called by muse, mutect2, varscan2
- ARHGAP44 | c.1299C>T p.I433= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs866859883, COSV99310326; called by mutect2, varscan2
- ARHGEF7 | c.1179C>T p.S393= (on ENST00000375741 / NM_001113511.2; = p.S215= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV54538507; called by muse, mutect2, varscan2
- ARPP19 | c.78A>G p.K26= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV51119100, COSV99993025; called by muse, mutect2
- ASH1L | c.6492C>T p.P2164= (on ENST00000368346 / NM_001366177.2; = p.P2159= on NM_018489.3) | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV64205379; called by muse, mutect2, varscan2
- ASMTL | c.687C>T p.I229= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV67243418; called by muse, mutect2, varscan2
- ASTN2 | c.2214G>A p.V738= (on ENST00000313400 / NM_001365069.1; = p.V687= on NM_014010.5) | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV57750262; called by muse, mutect2, varscan2
- ATXN2L | c.2061C>T p.P687= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV57365110; called by muse, mutect2
- BMPER | c.1317C>T p.R439= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs751915557, COSV51811570; called by muse, mutect2, varscan2
- CCDC66 | c.1686T>C p.T562= (on ENST00000394672 / NM_001353147.1; = p.T528= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV58301294; called by muse, mutect2, varscan2
- CCR2 | c.327G>A p.G109= | Silent (SNP) | VAF 57/324 reads (18%) | catalogued as rs1265926655, COSV52747593; called by muse, mutect2, varscan2
- CD163 | c.3195C>T p.F1065= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs763870346, COSV63129316; called by muse, varscan2
- CD300E | c.522C>T p.F174= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs145226937, COSV60789779; called by mutect2, varscan2
- CD33 | c.528C>T p.I176= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV51799902; called by muse, mutect2, varscan2
- CIT | c.2301C>T p.I767= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs747238115, COSV55859724; called by muse, mutect2, varscan2
- CNGB3 | c.498G>A p.K166= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100181479, COSV60684550; called by muse, mutect2, varscan2
- COL14A1 | c.4281C>T p.A1427= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV99918436; called by muse, mutect2, varscan2
- COL1A2 | c.831T>C p.G277= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as rs1800232, COSV51952744; called by muse, varscan2
- COL5A1 | c.348G>A p.L116= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV65664860; called by muse, mutect2, varscan2
- COPG1 | c.822C>T p.I274= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as rs772423585, COSV59112310; called by mutect2, varscan2
- CPA1 | c.1245G>A p.L415= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV50568343, COSV50576480; called by mutect2, varscan2
- CRY2 | c.522C>T p.A174= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV69888051; called by muse, mutect2, varscan2
- CSF2RA | c.60G>A p.L20= | Silent (SNP) | VAF 39/213 reads (18%) | catalogued as COSV62623454; called by mutect2, varscan2
- CSMD2 | c.9135C>T p.S3045= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV53878161; called by muse, mutect2, varscan2
- CYP2C9 | c.930C>T p.L310= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV53246365; called by muse, mutect2, varscan2
- CYP7B1 | c.174G>A p.V58= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as COSV100041092, COSV59582350; called by muse, mutect2, varscan2
- DCBLD1 | c.726C>T p.S242= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV51638143; called by muse, mutect2, varscan2
- DNAH7 | c.8301C>T p.I2767= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV56751539; called by mutect2, varscan2
- DNAH8 | c.9177C>T p.F3059= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100543698, COSV59424312; called by mutect2, varscan2
- DZIP1L | c.1662G>A p.K554= | Silent (SNP) | VAF 63/393 reads (16%) | catalogued as rs1349943938, COSV100551218; called by muse, mutect2, varscan2
- ECPAS | c.1755C>T p.A585= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV52191469; called by muse, varscan2
- ELFN2 | c.831C>T p.P277= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs936777694, COSV68743762; called by muse, mutect2, varscan2
- ENPP7 | c.477A>G p.K159= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs782678705, COSV60385269; called by muse, mutect2, varscan2
- EP400 | c.2988C>T p.I996= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV57762478; called by mutect2, varscan2
- EPHA1 | c.267G>A p.G89= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as rs1434685713, COSV51968492; called by muse, mutect2, varscan2
- EPHA10 | c.465C>T p.I155= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV60401976; called by mutect2, varscan2
- ERICH3 | c.1122C>T p.S374= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV58598953; called by muse, mutect2, varscan2
- ESYT3 | c.1152G>A p.R384= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV56679505; called by muse, mutect2, varscan2
- F7 | c.1005C>T p.F335= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs368893306; called by mutect2, varscan2
- FAT2 | c.12978G>A p.R4326= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55813043; called by muse, mutect2, varscan2
- FAT4 | c.13635G>A p.P4545= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs757657669, COSV58671354, COSV58695437; called by muse, mutect2, varscan2
- FNBP4 | c.1806C>T p.S602= | Silent (SNP) | VAF 35/243 reads (14%) | catalogued as COSV55446220; called by muse, mutect2, varscan2
- GNB1L | c.48C>T p.L16= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs779786717, COSV61547651; called by muse, mutect2, varscan2
- GOLGA4 | c.5073G>A p.L1691= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as COSV62709165, COSV62714550; called by muse, mutect2, varscan2
- GPHB5 | c.78C>T p.S26= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV58485509; called by muse, varscan2
- GPR137 | c.483C>A p.S161= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100464072; called by mutect2, varscan2
- GPX6 | c.453C>T p.F151= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV62656806; called by muse, mutect2, varscan2
- GSAP | c.1326C>T p.F442= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57528210; called by muse, mutect2, varscan2
- GUCY2C | c.2613C>T p.I871= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as rs1461802160, COSV53786669, COSV53795582; called by muse, mutect2, varscan2
- HIVEP3 | c.4542C>T p.P1514= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1445172452, COSV56009580; called by muse, mutect2, varscan2
- HS3ST4 | c.1116G>A p.Q372= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV58801168, COSV58834042; called by muse, mutect2, varscan2
- HTR6 | c.537G>A p.Q179= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV57031988; called by muse, varscan2
- IGHG4 | c.369C>T p.F123= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs749138952; called by mutect2, varscan2
- IGSF10 | c.7338T>C p.S2446= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV56368289; called by muse, mutect2, varscan2
- IL10RA | c.1389G>A p.L463= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs761796760, COSV57139691; called by muse, mutect2, varscan2
- INTS6L | c.1359G>A p.V453= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV66083607; called by muse, mutect2, varscan2
- IQUB | c.858G>A p.R286= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV61236782; called by muse, mutect2, varscan2
- ITGAX | c.1239C>T p.L413= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV51641357; called by mutect2, varscan2
- JCAD | c.123G>A p.Q41= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV64757880; called by muse, mutect2, varscan2
- KALRN | c.738C>T p.D246= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1172648613, COSV99562805; called by muse, mutect2, varscan2
- KCNQ3 | c.1287G>A p.R429= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs762220006, COSV66463642; called by muse, varscan2
- KCNQ3 | c.1050C>T p.I350= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV101195777; called by muse, mutect2, varscan2
- KIAA1217 | c.1368G>A p.R456= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV56812237; called by muse, mutect2, varscan2
- KIAA1614 | c.1726C>T p.L576= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV62550353; called by muse, mutect2
- KNSTRN | c.96G>A p.R32= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV51103425; called by muse, varscan2
- KRT6A | c.666G>A p.R222= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV58103584, COSV58103797; called by muse, mutect2, varscan2
- LAMB3 | c.3282G>A p.Q1094= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV50520204; called by muse, mutect2, varscan2
- LGI3 | c.631C>T p.L211= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs1466947284, COSV60442881; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.306C>T p.I102= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV53275389; called by mutect2, varscan2
- LRRIQ1 | c.4365C>T p.S1455= | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as rs1205301087, COSV67825814; called by muse, mutect2, varscan2
- MAGEC2 | c.453C>T p.F151= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs147374365, COSV55997699; called by muse, mutect2, varscan2
- MAP2K2 | c.168C>T p.A56= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs147814905; ClinVar: likely benign; called by muse, mutect2, varscan2
- MARCHF10 | c.1146G>A p.R382= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV60885161; called by muse, mutect2, varscan2
- MEGF8 | c.2010C>T p.S670= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV52074975; called by muse, mutect2, varscan2
- MROH2B | c.453C>T p.F151= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV68180921; called by mutect2, varscan2
- MUC16 | c.32019C>T p.S10673= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV67444213; called by muse, mutect2, varscan2
- MUC16 | c.24861G>A p.E8287= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs745365284, COSV67444228; called by muse, mutect2, varscan2
- MYH8 | c.5802C>T p.I1934= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as COSV101238080, COSV67959650; called by muse, mutect2, varscan2
- MYO1E | c.439C>T p.L147= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99894854; called by muse, mutect2, varscan2
- MYO3B | c.2850G>A p.Q950= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV58694171; called by muse, mutect2, varscan2
- MYPN | c.2838C>T p.I946= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV62731528; called by muse, mutect2, varscan2
- NELL1 | c.366G>A p.R122= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs267602818, COSV54238517; called by muse, mutect2, varscan2
- NME8 | c.1326G>A p.R442= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs749372977, COSV52246496; called by muse, mutect2, varscan2
- NPY5R | c.873G>A p.K291= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV58450948; called by muse, mutect2, varscan2
- NRCAM | c.348C>T p.T116= (on ENST00000379028 / NM_001371124.1; = p.T110= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV61031044; called by muse, mutect2, varscan2
- NRG2 | c.1485G>A p.G495= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV56829236; called by muse, mutect2, varscan2
- NRP2 | c.2655C>T p.G885= (on ENST00000360409 / NM_201266.2; = p.G880= on NM_003872.3) | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV63369992; called by muse, mutect2, varscan2
- ODR4 | c.1059C>T p.S353= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV55215501; called by muse, mutect2, varscan2
- OR10G2 | c.48C>T p.F16= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV73390299; called by muse, mutect2, varscan2
- OR10H5 | c.213C>T p.I71= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV58277405; called by muse, mutect2, varscan2
- OR10T2 | c.42C>T p.I14= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV57782170; called by muse, mutect2, varscan2
- OR13C4 | c.75C>T p.I25= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52925835; called by mutect2, varscan2
- OR4K1 | c.231C>T p.A77= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as COSV53458778; called by muse, mutect2, varscan2
- OR4X1 | c.312C>T p.F104= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV60722222, COSV60722666; called by muse, mutect2, varscan2
- OR4X2 | c.864G>A p.K288= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs373253273, COSV56583998; called by muse, mutect2, varscan2
- OR52K2 | c.606C>T p.I202= | Silent (SNP) | VAF 61/204 reads (30%) | catalogued as rs569235087, COSV57834566; called by muse, mutect2, varscan2
- OR9G1 | c.726C>T p.S242= | Silent (SNP) | VAF 24/331 reads (7%) | catalogued as rs931106242, COSV56447969, COSV56450671; called by muse, mutect2
- OR9Q2 | c.87C>T p.L29= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs755140204, COSV61111325; called by muse, mutect2, varscan2
- OTOGL | c.3399G>A p.K1133= (on ENST00000547103; = p.K1124= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV101509537, COSV72005597, COSV72007572; called by muse, mutect2, varscan2
- OTOP1 | c.1212C>T p.I404= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV56390653, COSV99587732; called by muse, mutect2, varscan2
- PATE2 | c.18C>T p.L6= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100653446, COSV62069115; called by muse, mutect2, varscan2
- PBX4 | c.651C>T p.F217= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as COSV52059834; called by mutect2, varscan2
- PCDH15 | c.3858G>A p.V1286= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100217480; called by muse, mutect2, varscan2
- PCLO | c.11616C>T p.T3872= | Silent (SNP) | VAF 48/333 reads (14%) | catalogued as COSV61615608; called by muse, mutect2, varscan2
- PDE8B | c.900G>A p.R300= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as COSV53732045; called by muse, mutect2, varscan2
- PDS5B | c.1560C>T p.A520= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as COSV59723221; called by muse, mutect2, varscan2
- POLR2E | c.483C>T p.A161= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV53123290; called by muse, mutect2, varscan2
- POLR3D | c.411C>T p.I137= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV60570480; called by mutect2, varscan2
- PPP1R13B | c.1425G>A p.S475= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs541818480, COSV52448534; called by mutect2, varscan2
- PPP2R2C | c.249C>T p.L83= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV58670223; called by mutect2, varscan2
- PROP1 | c.270G>A p.R90= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV57644600; called by muse, mutect2, varscan2
- PYGB | c.2286C>T p.I762= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs199570469, COSV53815607; called by mutect2, varscan2
- QSOX1 | c.1035C>T p.P345= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs766503224, COSV62579568; called by muse, varscan2
- RABGAP1 | c.2019G>A p.K673= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as COSV65379391; called by muse, mutect2, varscan2
- RBBP6 | c.486C>T p.F162= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV60503040; called by muse, mutect2, varscan2
- RGS9 | c.402G>A p.G134= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs267605003, COSV52222951; called by mutect2, varscan2
- RHOH | c.222G>A p.Q74= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV67804925; called by muse, mutect2, varscan2
- RP1 | c.5415C>T p.L1805= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1311244939, COSV55109911, COSV99609156; called by mutect2, varscan2
- SCN10A | c.3705G>A p.A1235= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs147376215; ClinVar: likely benign; called by mutect2, varscan2
- SDK2 | c.5085C>T p.A1695= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV66181115; called by muse, varscan2
- SEPTIN14 | c.1293G>A p.K431= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV66426092; called by muse, mutect2, varscan2
- SI | c.1224C>T p.L408= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV52265789; called by muse, mutect2, varscan2
- SLC29A2 | c.45G>A p.G15= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100237034; called by muse, varscan2
- SLC2A4 | c.216C>T p.I72= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV50300369; called by muse, mutect2, varscan2
- SLC35D2 | c.882C>T p.F294= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV53561568; called by muse, mutect2, varscan2
- SLITRK4 | c.7C>T p.L3= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV62022085, COSV62026078; called by mutect2, varscan2
- SMOX | c.462C>T p.F154= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1234892711, COSV53862922; called by muse, mutect2, varscan2
- SNX11 | c.330C>T p.V110= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV63658024; called by muse, mutect2, varscan2
- SOX1 | c.72C>T p.G24= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV58378362; called by muse, varscan2
- SPATA25 | c.675C>T p.S225= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as COSV99509725; called by muse, mutect2, varscan2
- SRSF7 | c.117T>C p.T39= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs1458335377, COSV57446352; called by muse, mutect2, varscan2
- STARD8 | c.588G>A p.K196= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs776573139, COSV99366407; called by mutect2, varscan2
- STC1 | c.420G>A p.R140= | Silent (SNP) | VAF 53/190 reads (28%) | catalogued as COSV51687700; called by muse, mutect2, varscan2
- STK36 | c.2094G>A p.R698= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99831138; called by mutect2, varscan2
- TAS2R4 | c.744C>T p.V248= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV56093164; called by muse, mutect2, varscan2
- TECTA | c.5739G>A p.K1913= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV50687829; called by muse, mutect2, varscan2
- TELO2 | c.1611C>T p.A537= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV51975970; called by muse, mutect2
- TGIF2LX | c.192C>T p.I64= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52213255, COSV52213926, COSV99383609; called by muse, mutect2, varscan2
- TLR10 | c.1393C>T p.L465= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV58299079; called by muse, mutect2, varscan2
- TMEM266 | c.102C>T p.T34= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs759691310, COSV66378510; called by muse, mutect2, varscan2
- TNN | c.1107G>A p.V369= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53421436; called by muse, mutect2
- TNN | c.3255C>T p.T1085= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV53421446; called by muse, mutect2, varscan2
- TRO | c.4158C>T p.F1386= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV51497413; called by mutect2, varscan2
- TRRAP | c.3096G>A p.K1032= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV62838676, COSV62854671; called by muse, mutect2
- TSC2 | c.528C>T p.F176= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as COSV54779540; called by muse, mutect2, varscan2
- TTN | c.89059C>T p.L29687= (on ENST00000591111; = p.L22263= on NM_003319.4) | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV59883656; called by muse, mutect2, varscan2
- TTN | c.63732G>A p.S21244= (on ENST00000591111; = p.S13820= on NM_003319.4) | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs187392843, COSV59883680; called by mutect2, varscan2
- UBAP2 | c.765G>A p.V255= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV62545147; called by muse, mutect2, varscan2
- UBE4B | c.921C>T p.S307= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53527074; called by muse, mutect2, varscan2
- UBQLNL | c.447C>T p.A149= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV66492591; called by muse, mutect2, varscan2
- UNC13C | c.4032G>A p.L1344= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1388982772, COSV52843010; called by mutect2, varscan2
- USP40 | c.3606C>T p.A1202= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99296028; called by muse, mutect2, varscan2
- UVSSA | c.285C>T p.P95= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs770825344, COSV66229265; called by mutect2, varscan2
- VAV1 | c.2391C>T p.D797= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV58378505; called by muse, varscan2
- VWA8 | c.3045A>C p.I1015= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV55691958; called by muse, mutect2, varscan2
- WDR33 | c.2298G>A p.G766= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100459725; called by muse, mutect2, varscan2
- WFS1 | c.726C>T p.I242= | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as rs71524381, COSV56987381; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- YWHAB | c.357C>T p.F119= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV62303862; called by muse, mutect2, varscan2
- ZBTB39 | c.1869C>T p.H623= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs745589596, COSV55627780; called by muse, mutect2, varscan2
- ZG16B | c.564G>A p.E188= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV66525625; called by muse, mutect2, varscan2
- ZKSCAN4 | c.456C>T p.L152= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV66023019; called by muse, mutect2
- ZNF700 | c.348G>A p.E116= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV54310819; called by muse, mutect2, varscan2
- ZNF705D | c.702G>A p.G234= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1402784245, COSV101308345; called by mutect2, varscan2
- AC073310.1 | n.205C>T | RNA (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- ANKRD10 | c.456-872C>T | Intron (SNP) | VAF 22/148 reads (15%) | catalogued as COSV99941068; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500281 C>T | 5'Flank (SNP) | VAF 14/65 reads (22%) | catalogued as rs757611317; called by mutect2, varscan2
- ATP2A2 | c.*3828T>G | 3'UTR (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100428474; called by muse, mutect2, varscan2
- CHCHD2P9 | n.13A>G | RNA (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5584C>T | 3'UTR (SNP) | VAF 31/90 reads (34%) | catalogued as COSV57051965; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1930C>T | Intron (SNP) | VAF 15/102 reads (15%) | catalogued as rs765468404, COSV65797910; called by mutect2, varscan2
- GLYCTK | c.*1101C>T | 3'UTR (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- MTRNR2L6 | chr7:142671076 G>A | 3'Flank (SNP) | VAF 15/111 reads (14%) | catalogued as rs759075223; called by muse, mutect2, varscan2
- NACA | c.71-2307C>T | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100771165; called by muse, mutect2, varscan2
- OBSCN | c.11660-2505C>T | Intron (SNP) | VAF 17/68 reads (25%) | catalogued as COSV52839949; called by muse, mutect2, varscan2
- OR2U1P | n.497G>A | RNA (SNP) | VAF 16/109 reads (15%) | catalogued as rs1453778472; called by mutect2, varscan2
- P4HTM | c.1074-41C>T | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as COSV59086000; called by muse, mutect2, varscan2
- PAX7 | c.1402+27C>T | Intron (SNP) | VAF 7/36 reads (19%) | catalogued as COSV64748373; called by muse, mutect2
- RPS12 | c.337-172G>A | Intron (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100016293, COSV57768000; called by muse, mutect2, varscan2
- SPG7 | c.1303+4203C>T | Intron (SNP) | VAF 36/149 reads (24%) | catalogued as COSV99244720; called by muse, mutect2, varscan2
- STMP1 | chr7:135660156 C>T | 5'Flank (SNP) | VAF 9/42 reads (21%) | catalogued as rs1286460703; called by muse, mutect2, varscan2
